Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-A8FO, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-A8FO-01A (Primary Tumor).

Collection Date:

FINAL DIAGNOSIS:

PART 1: LYMPH NODES, RIGHT PELVIS, DISSECTION -
EIGHTEEN (18) LYMPH NODES, NEGATIVE FOR METASTATIC CARCINOMA (0/18).

PART 2: LYMPH NODES, LEFT PELVIS, DISSECTION -
NINETEEN (19) LYMPH NODES, NEGATIVE FOR METASTATIC CARCINOMA (0/19).

PART 3: FAT PAD, ANTERIOR, EXCISION-
BENIGN FIBROADIPOSE TISSUE.

PART 4: PROSTATE, BILATERAL SEMINAL VESICLES AND DISTAL VASA DEFERENTIA, RADICAL PROSTATECTOMY -

- A. INVASIVE PROSTATIC ADENOCARCINOMA, ACINAR TYPE, GLEASON SCORE 4 + 3 = 7 WITH DUCTAL FEATURES.
- B. PROMINENT MUCINOUS FIBROPLASIA.
- C. CARCINOMA INVOLVES BOTH RIGHT AND LEFT LOBES AND HAS A MAXIMAL NODULAR DIAMETER OF 1.7 cm.
- D. CARCINOMA INVOLVES APPROXIMATELY 15% OF THE EXAMINED PROSTATE VOLUME.
- E. CARCINOMA SHOWS FOCAL EXTRACAPSULAR EXTENSION.
- F. EXTRACAPSULAR EXTENSION IS SEEN IN THE REGION OF THE POSTERIOR LEFT APEX AND LEFT MID PROSTATE (slide 4X, 4Y).
- G. BILATERAL SEMINAL VESICLES AND DISTAL VASA DEFERENTIA ARE FREE OF CARCINOMA.
- H. ALL EXAMINED SURGICAL RESECTION MARGINS ARE FREE OF CARCINOMA.
- I. PERINEURAL INVASION IS IDENTIFIED.
- J. ANGIOLYMPHATIC INVASION IS NOT IDENTIFIED.
- K. HIGH-GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA IS IDENTIFIED.
- L. TNM PATHOLOGIC STAGE (AJCC 7th EDITION): pT3a N0 MX.
- M. TNM HISTOLOGIC GRADE = G3-4.
- N. BACKGROUND PROSTATIC PARENCHYMA WITH FOCAL ATROPHIC FEATURES.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY PROSTATE TUMORS

CLINICAL DATA:	PSA value: 9.9
INVASIVE CA IDENTIFIED?:	Yes
TUMOR HISTOLOGY:	Adenocarcinoma NOS
	Ductal adenocarcinoma
PRIMARY GLEASON GRADE:	4
SECONDARY GLEASON GRADE:	3
GLEASON SUM SCORE:	7
WEIGHT OF PROSTATE:	39.45gm
TUMOR SIZE:	Maximum dimension: 1.7 cm
LOBE LATERALITY:	Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR:	5 - 25%
MULTIFOCAL DISEASE:	Yes
HIGH GRADE PIN:	Yes - NOS
EXTRAPROSTATIC EXTENSION:	Yes - Focal
PERINEURAL INVASION:	Yes
ANGIOLYMPHATIC INVASION:	No
SEMINAL VESICLE INVASION:	No
SURGICAL MARGIN INVOLVEMENT:	All surgical margins free of tumor
LYMPH NODES EXAMINED:	37
LYMPH NODES POSITIVE:	0
T STAGE, PATHOLOGIC:	pT3a
N STAGE, PATHOLOGIC:	pN0
M STAGE, PATHOLOGIC:	pMX
HISTOLOGIC GRADE:	G3-4, Poorly differentiated/undifferentiated

*Pw-TSS, ductal = 70%
OK*

TCO.0.3

*Adenocarcinoma acinar & ductal
path 8500/13
Adenocarcinoma, ductal NOS
Site: Prostate NOS C61.9 8500/13
11/17/14*

Source: NCI Genomic Data Commons file 9dc17349-5c12-417b-b795-ce2475891b2e (TCGA-EJ-A8FO.72728A33-3CFC-43B5-B88C-B2DC34C83207.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).